Gene-level copy-number profile of tumor specimen TCGA-19-0957-02A from TCGA case TCGA-19-0957, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.5 years (17,714 days).
Specimen TCGA-19-0957-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.c3819352-5915-487c-89c2-7b943d8436a2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-0957-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/3adec9b6-f4a3-4865-ba87-647d8f9ebe39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 4,606; copy number 2: 51,089; copy number 3: 3,379; copy number 4: 555; copy number 5: 18; copy number 6: 4; copy number 29: 6; copy number 30: 1; copy number 31: 33; copy number 32: 8; copy number 41: 2; copy number 44: 10; copy number 45: 6; copy number 46: 10; copy number 53: 12; copy number 71: 12.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:70,564,267–70,564,437, 1 gene: AL445264.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 122 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:100,609,601–100,695,479, 3 genes, copy number 6: ADGRG7, AC069223.1, GMFBP1.
- chr4:51,843,000–52,551,574, 10 genes, copy number 46 (within-gene range 1–46): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1.
- chr4:52,862,317–52,866,835, 1 gene, copy number 41: RASL11B.
- chr4:52,945,649–52,958,087, 1 gene, copy number 41: AC023154.1.
- chr4:53,997,415–54,376,752, 11 genes, copy number 44–45: AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1.
- chr4:61,201,258–62,078,335, 1 gene, copy number 53 (within-gene range 1–53): ADGRL3.
- chr4:61,420,246–62,510,771, 11 genes, copy number 53: AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11.
- chr6:45,573,346–46,839,782, 18 genes, copy number 5: RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A.
- chr7:138,645,671–138,646,448, 1 gene, copy number 6: AC013429.1.
- chr12:57,610,180–57,984,761, 33 genes, copy number 31: ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,244,378–58,244,865, 1 gene, copy number 30: RPL21P103.
- chr12:61,708,259–62,279,150, 5 genes, copy number 32 (within-gene range 1–32): TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1.
- chr12:67,351,436–67,442,559, 3 genes, copy number 32: MRPL40P1, NTAN1P3, LINC02420.
- chr12:67,929,235–68,234,686, 5 genes, copy number 44 (within-gene range 1–55): LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70.
- chr12:68,686,951–68,971,570, 12 genes, copy number 71 (within-gene range 1–71): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:71,439,798–71,667,725, 6 genes, copy number 29 (within-gene range 4–29): LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1.

Autosomal genes at a single copy (total copy number 1): 4,606. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
